Gene-level copy-number profile of tumor specimen ALCH-B1KY-TTP1-A from ALCHEMIST case ALCH-B1KY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.5 years (26,098 days).
Specimen ALCH-B1KY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file baf483a1-43a8-4174-8d31-37bc50e5a7dd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1KY-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/723b821e-e3c5-4f7f-a5b9-c609447de081

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 1,215; copy number 2: 24,755; copy number 3: 20,810; copy number 4: 9,035; copy number 5: 2,091; copy number 6: 295; copy number 7: 84; copy number 9: 31; copy number 10: 66; copy number 35: 2.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:52,794,768–52,809,009, 1 gene: ITIH3.
- chr7:65,023,204–65,023,310, 1 gene: RNU6-1229P.
- chr8:22,106,874–22,164,479, 5 genes: NUDT18, HR, REEP4, LGI3, SFTPC.
- chr8:22,169,338–22,171,710, 1 gene (within-gene range 0–1): AC105206.1.
- chr9:61,581,813–61,662,690, 4 genes: AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr10:132,783,179–132,786,147, 1 gene (within-gene range 0–2): NKX6-2.
- chr12:67,929,235–67,970,017, 1 gene: LINC01479.
- chr17:2,375,061–2,401,104, 3 genes (within-gene range 0–2): AC006435.2, MNT, AC006435.1.
- chr21:44,133,610–44,210,114, 1 gene (within-gene range 0–35): GATD3A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,569 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:236,518,000–248,937,043, 270 genes, copy number 6 (broad region; genes not listed).
- chr4:932,387–958,656, 1 gene, copy number 6: TMEM175.
- chr5:166,382,305–181,342,213, 366 genes, copy number 5 (broad region; genes not listed).
- chr6:38,168,451–38,640,148, 1 gene, copy number 6 (within-gene range 4–6): BTBD9.
- chr6:38,481,692–51,464,765, 262 genes, copy number 5–10 (broad region; genes not listed).
- chr13:27,435,643–27,450,591, 1 gene, copy number 5 (within-gene range 3–5): MTIF3.
- chr13:63,667,681–112,887,168, 512 genes, copy number 5 (broad region; genes not listed).
- chr13:114,306,646–114,337,626, 3 genes, copy number 5: CLCP2, CHAMP1, LINC01054.
- chr16:11,555–231,472, 25 genes, copy number 5: DDX11L10, WASH4P, MIR6859-4, Z84723.1, WASIR2, IL9RP3, POLR3K, SNRNP25, RHBDF1, Z69720.2, MPG, NPRL3, Z69720.1, Z69666.1, HBZ, HBM, HBZP1, HBAP1, HBA2, HBA1, Y_RNA, HBQ1, Z69706.1, LUC7L, Z69890.1.
- chr16:3,144,015–35,912,516, 1,108 genes, copy number 5–7 (broad region; genes not listed).
- chr16:85,027,751–85,094,230, 1 gene, copy number 5: KIAA0513.
- chr19:9,083,112–9,122,492, 5 genes, copy number 5: OR1M4P, OR1M1, OR7G2, OR7G1, OR7G15P.
- chr21:44,172,169–44,194,338, 2 genes, copy number 35: AP001056.2, AP001056.1.
- chr22:21,103,016–21,128,063, 3 genes, copy number 6–7: BCRP2, AP000550.1, POM121L7P.
- chr22:21,167,758–21,203,755, 3 genes, copy number 6 (within-gene range 6–7): FAM230B, AP000550.2, FAM247A.
- chr22:21,228,760–21,325,042, 6 genes, copy number 5–6 (within-gene range 5–14): AP000550.3, E2F6P3, POM121L8P, BCRP6, FAM230H, AP000552.2.

Autosomal genes at a single copy (total copy number 1): 1,175. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
